Surgical pathology report (de-identified scan), TCGA case TCGA-PD-A5DF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Fox Chase, specimen TCGA-PD-A5DF-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN:
SURGICAL PATHOLOGY REPORT

DOB: .
Sex: F
Location:
Date Collected:
Date Received:
Physician: .
Copy To:
Clinical History/Diagnosis: Right Liver Lobe "Hepatoma".

*ICD-O-3 NOS
Carcinoma, hepatocellular
8/20/13
Site: Liver C22.0
JW 5/24/13*

Source of Specimen(s):
1: Right colonic mesenteric lymph node
2: right lobe liver segment
3: gallbladder, segment 5 and 6 of liver, right colon

Gross Description:
Received in three parts.
Source of Tissue: 1. Labeled #1, "right colonic mesenteric lymph node"

Gross Description: Received fresh labeled "right colonic mesenteric lymph node". It consists of a firm yellow-tan lymph node measuring 0.7 x 0.5 x 0.5 cm. The lymph node is bisected and entirely submitted in 1A.

Source of Tissue: 2. Labeled #2, "right lobe liver segment"

Frozen Section Diagnosis: 2FS- CONSISTENT WITH HEPATOCELLULAR
CARCINOMA
PER

Gross Description: Received fresh labeled "right lobe liver segment". It consists of a firm white-tan well-circumscribed nodule measuring 0.5 x 0.5 x 0.3 cm. The nodule is bisected and entirely submitted in 2FS.

Source of Tissue: 3. Labeled #3, "gallbladder, segments 5 and 6 of liver, right colon"

Gross Description: Received fresh labeled "gallbladder, segments 5 and 6 of liver, right colon". It consists of a large liver mass with attached gallbladder and attached segment of large bowel. The liver mass measures 21 x 17 x 13.5 cm in greatest dimension. The mass is serially sectioned to reveal a golden-yellow, soft diffusely necrotic cut surface. Also the mass comes within 2 cm of the closest cauterized liver margin. A suture is identified at the liver margin. The margin is inked green. The attached short segment of terminal ileum measures 7 cm in length and 3 cm in circumference. The terminal ileum is

Diagnostic Discrepancy		/

[page 2 of 2]
opened to show a diffusely hemorrhagic smooth mucosal lining with no discrete masses present. The appendix measures 8.5 x 0.5 x 0.5 cm. The appendix is sectioned to reveal a homogeneous, soft tan-pink cut surface with no discrete masses present. The attached segment of large bowel is completely adhered to the previously described liver mass and measures 39 cm in length and 5 cm in circumference. The tumor does not appear to infiltrate the large bowel wall. The large bowel mucosa is red-brown and diffusely hemorrhagic with no discrete lesions identified. The gallbladder measures 8 x 4 x 4 cm. The gallbladder is also grossly adhered to tumor. The cystic duct is patent measuring 0.5 cm in diameter. The gallbladder is opened to reveal approximately 20 cc of dark-green viscid bile. The mucosa is velvety, bile stained with no mucosal ulcerations or polyps identified. Representative sections submitted in 3A-3K.

Designation of Sections: 3A- tumor with closest liver margin inked green, 3B- additional perpendicular sections of the liver margin, 3C-3D- tumor with closest capsule, 3E- tumor with adjacent normal liver, 3F- proximal and distal right colon margin, 3G-3H- tumor in relation to right colon, 3I- cystic duct, 3J- tumor in relation to gallbladder, 3K- appendix

Final Diagnosis:

1. Right colonic mesenteric lymph node, excision:

No tumor seen in one lymph node (0/1).

2. Liver, right lobe segment, excision:

Hepatocellular carcinoma.

3. Gallbladder, segments 5 and 6 of liver, right colon, excision:

Hepatocellular carcinoma, grade II/IV.

- The 21 cm carcinoma invades serosa of ascending colon.

- Angiolymphatic invasion is identified.

- Surgical resection margins are free of carcinoma.

Gallbladder with chronic cholecystitis.

Cecum and terminal ileum with no diagnostic abnormalities recognized.

Appendix with partial fibrosis obliteration of the lumen.

pTNM: T4 N0 Mx

Source: NCI Genomic Data Commons file abbb4bf3-b760-4d8f-a257-8f425c11b0e0 (TCGA-PD-A5DF.8D63D119-DC81-45FE-9F02-8228A7160C55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).